Somatic mutation profile of tumor specimen TCGA-66-2773-01A (aliquot TCGA-66-2773-01A-01D-1267-08) from TCGA case TCGA-66-2773, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.4 years (25,355 days).
Specimen TCGA-66-2773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1b6babe-8993-41ab-a7f0-8f6f517f5f34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2773-11A (Solid Tissue Normal), aliquot TCGA-66-2773-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d461ca0f-a11f-4e96-94ef-d7c8d055948b

The open-access MAF lists 597 somatic variants for this specimen: 426 protein-altering or splice-affecting, 159 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 373, Silent 159, Nonsense Mutation 33, Frame Shift Del 7, Splice Site 7, Intron 3, RNA 3, 5'UTR 3, Splice Region 2, Nonstop Mutation 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 30/131 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- KEAP1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 23/119 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV50260372, COSV50272556, COSV50274400; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 40/421 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- A2ML1 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV55289222, COSV55295444; called by muse, mutect2, varscan2
- ABCA1 | c.2725C>T p.R909* | Nonsense Mutation (SNP) | VAF 68/328 reads (21%) | catalogued as rs1400383111, CD013124, CM003220, COSV66065525; called by muse, mutect2, varscan2
- ABCA12 | c.6973C>G p.H2325D (on ENST00000272895 / NM_173076.3; = p.H2007D on NM_015657.3) | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55955818, COSV55975923; called by muse, mutect2, varscan2
- ABCC11 | c.3869G>A p.R1290K | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62322615; called by muse, mutect2
- ABCC12 | c.1821G>C p.Q607H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60913249; called by muse, mutect2
- ABHD14A-ACY1 | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 158/399 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); catalogued as COSV68343896; called by muse, mutect2, varscan2
- ABLIM3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV58642324; called by muse, mutect2
- AC004832.3 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 167/580 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56741685; called by muse, mutect2, varscan2
- ACAD11 | c.2324G>C p.R775T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV53895411; called by muse, mutect2
- ACSM2B | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 78/953 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61657166; called by muse, mutect2
- ACSM3 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV55500987; called by muse, mutect2, varscan2
- ADAMDEC1 | c.647C>A p.A216E | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV56474878; called by muse, mutect2, varscan2
- ADAMTS19 | c.2248G>T p.D750Y | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50742272; called by muse, mutect2, varscan2
- ADAMTS20 | c.3199G>T p.E1067* | Nonsense Mutation (SNP) | VAF 29/171 reads (17%) | catalogued as COSV67130156; called by muse, varscan2
- ADAMTS4 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 361/1313 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63487657; called by muse, mutect2, varscan2
- ADAMTS9 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55779315; called by muse, mutect2, varscan2
- ADCY1 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52033217, COSV52039137; called by muse, mutect2, varscan2
- ADH1C | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 56/343 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV72463436; called by muse, mutect2, varscan2
- AEBP1 | c.2329C>A p.R777S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV56257006; called by muse, mutect2, varscan2
- AJAP1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as rs765357051, COSV65450083; called by muse, mutect2, varscan2
- AKAP13 | c.7974G>C p.Q2658H (on ENST00000394518 / NM_007200.5; = p.Q2662H on NM_006738.6) | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV63454195; called by muse, mutect2, varscan2
- AKAP6 | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55211294; called by muse, mutect2, varscan2
- ALDH3B2 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 9/275 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100824165, COSV62427985; called by muse, mutect2
- ALG10B | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as COSV58142966, COSV58144103; called by muse, mutect2
- ALG3 | c.1152C>G p.L384= | Splice Region (SNP) | VAF 28/372 reads (8%) | catalogued as COSV56611094; called by muse, mutect2
- ALKBH6 | c.316C>G p.L106V (on ENST00000252984 / NM_001297701.2; = p.L134V on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as COSV53324459; called by muse, mutect2
- ANK1 | c.5479-1G>C p.X1827_splice | Splice Site (SNP) | VAF 37/176 reads (21%) | catalogued as COSV55875976; called by muse, mutect2, varscan2
- ANKLE2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as COSV61708139, COSV61709002; called by muse, mutect2, varscan2
- ANKRD11 | c.4214C>T p.S1405F | Missense Mutation (SNP) | VAF 21/558 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs977735530, COSV56359417; called by muse, mutect2
- ANKZF1 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55476183, COSV55476909; called by muse, mutect2, varscan2
- ANO10 | c.999G>C p.M333I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV52728770, COSV52730285; called by muse, mutect2
- APTX | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV58928415; called by muse, mutect2, varscan2
- ARHGAP17 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV51506284, COSV99253764; called by muse, mutect2, varscan2
- ARHGAP4 | c.2795C>G p.S932* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV61686089; called by muse, mutect2, varscan2
- ARHGAP4 | c.2687C>G p.S896C | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV61686092; called by muse, mutect2, varscan2
- ARRDC3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.138); catalogued as COSV54364976; called by muse, mutect2
- ARSG | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1298725640, COSV71592977; called by muse, mutect2, varscan2
- ASB4 | c.577T>A p.F193I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV57944432; called by muse, mutect2, varscan2
- ASB4 | c.1200C>A p.C400* | Nonsense Mutation (SNP) | VAF 38/240 reads (16%) | catalogued as COSV57944447, COSV57948426; called by muse, mutect2, varscan2
- ASIC2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 15/363 reads (4%) | catalogued as COSV56759742, COSV56769104; called by muse, mutect2
- ASIC4 | c.1166A>G p.Y389C (on ENST00000347842 / NM_182847.3; = p.Y408C on NM_018674.6) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61731535; called by muse, mutect2, varscan2
- ASXL3 | c.1379C>G p.T460S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.985); catalogued as COSV52463442; called by muse, mutect2, varscan2
- ATF7IP | c.3719A>G p.Y1240C | Missense Mutation (SNP) | VAF 157/546 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53769214; called by muse, mutect2, varscan2
- ATIC | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 145/531 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52692682; called by muse, mutect2, varscan2
- ATP10B | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58778436; called by muse, mutect2, varscan2
- ATP13A4 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs777828353, COSV55068396, COSV99794497; called by muse, mutect2
- ATXN7 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 17/205 reads (8%) | catalogued as COSV55749832; called by muse, mutect2
- AVPR2 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61686088; called by muse, mutect2, varscan2
- BACH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57590039, COSV57592010; called by muse, mutect2, varscan2
- BAIAP3 | c.3563G>C p.*1188Sext*39 | Nonstop Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV50103885; called by muse, mutect2
- BAZ1A | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62409863; called by muse, mutect2, varscan2
- BCL11A | c.736G>C p.E246Q (on ENST00000335712 / NM_001365609.1; = p.E280Q on NM_018014.4) | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV59628232; called by muse, mutect2, varscan2
- BDP1 | c.4120G>C p.E1374Q | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as COSV62430746, COSV62433493; called by muse, mutect2
- BOD1L1 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50009746; called by muse, mutect2, varscan2
- BRINP3 | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs527770000, COSV66520590, COSV66524549; called by muse, mutect2, varscan2
- BTBD3 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV54778818; called by muse, mutect2, varscan2
- BTN2A2 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV61857105, COSV61857765; called by muse, mutect2
- C12orf42 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59381460; called by muse, varscan2
- C16orf91 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 86/454 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as rs199709082, COSV59949975; called by muse, mutect2, varscan2
- CABIN1 | c.3464C>G p.S1155* | Nonsense Mutation (SNP) | VAF 53/371 reads (14%) | catalogued as COSV54080590, COSV99572802; called by muse, mutect2, varscan2
- CACNA1E | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs867320481, COSV62390364; called by muse, mutect2, varscan2
- CAMSAP3 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV50332611; called by muse, mutect2
- CAPNS2 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50895028; called by muse, mutect2, varscan2
- CARMIL1 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1269369743, COSV61516376; called by muse, mutect2
- CARMIL2 | c.3547G>T p.E1183* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV54666994; called by muse, mutect2
- CBX7 | c.264C>A p.D88E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV53358800; called by muse, mutect2, varscan2
- CD22 | c.2384C>G p.T795S | Missense Mutation (SNP) | VAF 12/337 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV50051446; called by muse, mutect2
- CDC45 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 115/506 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54244673; called by muse, varscan2
- CDH18 | c.2075G>A p.R692K | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56915577; called by muse, mutect2, varscan2
- CDH19 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.969); catalogued as rs533652186, COSV50955575; called by muse, mutect2, varscan2
- CEP78 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.093); catalogued as COSV52846768; called by muse, mutect2, varscan2
- CLEC1B | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 54/504 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs373622374, COSV53725250; called by muse, mutect2, varscan2
- CLIC5 | c.994C>A p.R332S (on ENST00000185206 / NM_001370649.1; = p.R173S on NM_016929.5) | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51756013, COSV51757760; called by muse, mutect2, varscan2
- CNGA4 | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 114/700 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56410850; called by muse, varscan2
- CNTN6 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63168976; called by muse, mutect2, varscan2
- COL13A1 | c.1012G>T p.A338S (on ENST00000398978 / NM_001130103.2; = p.A281S on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV62568786; called by muse, varscan2
- COL22A1 | c.2266G>T p.G756W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV57332827; called by muse, mutect2, varscan2
- COL7A1 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 82/249 reads (33%) | catalogued as COSV60394179; called by muse, mutect2, varscan2
- CPSF2 | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54097897; called by muse, mutect2, varscan2
- CRAMP1 | c.1509G>C p.L503F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV51961270; called by muse, mutect2, varscan2
- CRNKL1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 14/207 reads (7%) | catalogued as COSV55626315; called by muse, mutect2
- CRTC3 | c.1493C>G p.P498R | Missense Mutation (SNP) | VAF 30/425 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51595901; called by muse, mutect2
- CSMD3 | c.7913C>T p.P2638L (on ENST00000297405 / NM_001363185.1; = p.P2534L on NM_052900.3) | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52155894; called by muse, mutect2
- CSMD3 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52155913; called by muse, mutect2
- CSPG4 | c.4942C>G p.Q1648E | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57893724; called by muse, mutect2
- CST6 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV56410105; called by muse, mutect2, varscan2
- CTDSP2 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 97/634 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV66079893; called by muse, mutect2, varscan2
- CTSS | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 81/610 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV64566192; called by muse, mutect2, varscan2
- CYP2C8 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV64876811, COSV64877238; called by muse, mutect2
- CYP4F3 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 89/272 reads (33%) | catalogued as COSV55409051; called by muse, mutect2, varscan2
- DCAF1 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.117); catalogued as COSV60042258; called by muse, mutect2, varscan2
- DDHD2 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV68157674; called by muse, mutect2, varscan2
- DDX59 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58751515; called by muse, mutect2
- DICER1 | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.926); catalogued as COSV58618266; called by muse, mutect2
- DLC1 | c.1555C>G p.H519D (on ENST00000276297 / NM_001348081.2; = p.H82D on NM_006094.5) | Missense Mutation (SNP) | VAF 63/408 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV52299762; called by muse, mutect2, varscan2
- DMGDH | c.2364A>T p.E788D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54862552; called by muse, mutect2, varscan2
- DNAH12 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.237); catalogued as COSV60856528, COSV60858110; called by muse, mutect2, varscan2
- DNAH7 | c.8855G>A p.G2952D | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs965763337, COSV56760230; called by muse, mutect2, varscan2
- DNAI2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 92/183 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.157); catalogued as COSV56758097; called by muse, mutect2, varscan2
- DOCK10 | c.6305G>A p.R2102K | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51376593; called by muse, mutect2, varscan2
- DOK6 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV66929489; called by muse, mutect2, varscan2
- DRC3 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs199972472; called by muse, mutect2, varscan2
- EFCAB5 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 51/369 reads (14%) | catalogued as COSV57928539; called by muse, mutect2, varscan2
- EGFLAM | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV59298844; called by muse, mutect2, varscan2
- EIF2D | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as rs1296295234, COSV55113259; called by muse, mutect2, varscan2
- EIF3K | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 61/478 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs764778412, COSV50263701; called by muse, mutect2, varscan2
- ELOVL4 | c.510G>C p.W170C | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63953686; called by muse, mutect2, varscan2
- ENAM | c.3076G>C p.E1026Q | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV68535740, COSV68536016; called by muse, mutect2, varscan2
- EOMES | c.1599C>G p.I533M | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55412118; called by muse, mutect2
- EOMES | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV55412130; called by muse, mutect2
- EP300 | c.6367G>T p.G2123W | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54330965; called by muse, mutect2, varscan2
- EPHB3 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 65/487 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs531602325, COSV57805413; called by muse, mutect2, varscan2
- ERBB3 | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57250940; called by muse, mutect2, varscan2
- ERLIN1 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.122); catalogued as COSV64940984, COSV64941416; called by muse, mutect2, varscan2
- ERLIN2 | c.459A>T p.Q153H | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52420389; called by muse, mutect2, varscan2
- ESCO2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV59414250; called by muse, mutect2, varscan2
- ETS1 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.965); catalogued as COSV60092990; called by muse, mutect2, varscan2
- FAM117B | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57417833; called by muse, mutect2
- FAM135B | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50524859, COSV50537129, COSV99356718; called by muse, mutect2
- FANCF | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV59416036; called by muse, mutect2
- FARP2 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218491442, COSV50870514; called by muse, mutect2
- FASTKD3 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV52942850, COSV52944214; called by muse, mutect2, varscan2
- FBXL4 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57746468; called by muse, mutect2
- FCRL5 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV62513448; called by muse, mutect2, varscan2
- FGD4 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779572971, CM1511855, COSV56782871; called by muse, mutect2, varscan2
- FIGN | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV60765738; called by muse, varscan2
- FKBP2 | c.125G>A p.C42Y | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58587790; called by muse, mutect2
- FLG | c.7730C>G p.S2577* | Nonsense Mutation (SNP) | VAF 114/1157 reads (10%) | catalogued as COSV64240378; called by muse, mutect2, varscan2
- FLG | c.6620G>C p.G2207A | Missense Mutation (SNP) | VAF 352/1967 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.485); catalogued as COSV64240385, COSV64249909; called by muse, mutect2, varscan2
- FLNC | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 82/371 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs766755439, COSV100367735, COSV57954261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751831209, COSV55357756; called by muse, mutect2, varscan2
- FMN2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as rs370593818, COSV60426880; called by muse, mutect2, varscan2
- FSCN3 | c.145-1G>A p.X49_splice | Splice Site (SNP) | VAF 21/178 reads (12%) | catalogued as COSV50000792; called by muse, mutect2, varscan2
- GALNT5 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.436); catalogued as rs1286119361, COSV52037158; called by muse, mutect2
- GIMAP6 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV61033129; called by muse, mutect2, varscan2
- GLIPR1L2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs567529302, COSV57553658; called by muse, mutect2, varscan2
- GNA14 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 128/645 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV59022358; called by muse, varscan2
- GOLGB1 | c.5963A>G p.K1988R | Missense Mutation (SNP) | VAF 292/675 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.364); catalogued as COSV61464652; called by muse, mutect2, varscan2
- GRIA4 | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV56891294; called by muse, mutect2
- GRIK2 | c.2640G>T p.Q880H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV59729147; called by mutect2, varscan2
- GTPBP1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53284177; called by muse, mutect2
- H2BC5 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 116/656 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV56799773, COSV56799958, COSV56800667; called by muse, mutect2, varscan2
- HMCN1 | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV54893215; called by muse, mutect2, varscan2
- HNF4A | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs550287415, COSV57381863; called by muse, mutect2, varscan2
- HOXB8 | c.710C>A p.A237E | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV53310251; called by muse, mutect2, varscan2
- HOXC11 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 87/437 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV54533012; called by muse, mutect2, varscan2
- HOXC9 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 54/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754597030, COSV57716617; called by muse, mutect2, varscan2
- HOXD4 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs949417378, COSV60459738; called by muse, mutect2
- IBSP | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs774318328, COSV56895364; called by muse, mutect2, varscan2
- IDO1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53713741; called by muse, mutect2, varscan2
- IFIH1 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55126131; called by muse, mutect2, varscan2
- IP6K3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs145429872; called by muse, mutect2, varscan2
- IQCH | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1228091606, COSV60051519; called by muse, mutect2, varscan2
- IQCN | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV66573818; called by muse, mutect2, varscan2
- IRAK3 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 23/458 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV54161043; called by muse, mutect2
- IRX3 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV61668107; called by muse, mutect2, varscan2
- ITGB2 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56609560; called by muse, mutect2
- ITPR1 | c.5668G>C p.E1890Q (on ENST00000354582; = p.E1835Q on NM_002222.7) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV56977674; called by muse, varscan2
- JAML | c.550C>G p.R184G (on ENST00000356289 / NM_001098526.2; = p.R174G on NM_153206.3) | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.306); catalogued as COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as rs760886074, COSV58019454; called by muse, mutect2, varscan2
- KAT8 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV54896284; called by muse, mutect2
- KBTBD4 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV58597032; called by muse, mutect2, varscan2
- KCNH4 | c.1728C>G p.F576L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52916733, COSV99237120; called by muse, mutect2, varscan2
- KCNJ11 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306643774, COSV60594569; called by muse, mutect2
- KCNJ4 | c.492C>A p.D164E | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57856771; called by muse, varscan2
- KCNMB1 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV51131712; called by muse, mutect2, varscan2
- KCNMB4 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs775592650, COSV50691110; called by muse, mutect2, varscan2
- KCNT2 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV54074877, COSV54098825, COSV99656794; called by muse, mutect2, varscan2
- KIAA1549L | c.2381G>A p.R794Q (on ENST00000321505; = p.R1091Q on NM_012194.3) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55772245; called by muse, mutect2, varscan2
- KIF1B | c.4663G>A p.E1555K (on ENST00000377086 / NM_001365952.1; = p.E1509K on NM_015074.3) | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV55807385, COSV55814149; called by muse, mutect2
- KIR3DL2 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 373/1071 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99552082, COSV99552152; called by muse, mutect2, varscan2
- KMT2D | c.6694G>A p.G2232S | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV56429848, COSV99980434; called by muse, mutect2, varscan2
- KRT23 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 121/594 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52927531; called by muse, mutect2, varscan2
- KRT6B | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.443); catalogued as COSV52883204; called by muse, mutect2, varscan2
- LACTB | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV56055713; called by muse, mutect2
- LAPTM4B | c.703G>A p.D235N (on ENST00000445593; = p.D144N on NM_018407.6) | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as COSV71453978; called by muse, mutect2, varscan2
- LARP4B | c.1267C>G p.P423A | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV60221091; called by muse, mutect2, varscan2
- LCT | c.3356del p.V1119Afs*4 | Frame Shift Del (DEL) | VAF 70/280 reads (25%) | catalogued as COSV51554794; called by mutect2, pindel, varscan2
- LMAN1 | c.1396T>C p.C466R | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51826578; called by muse, mutect2, varscan2
- LRP1B | c.8176G>T p.A2726S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV101255467, COSV67207403; called by muse, varscan2
- LRP1B | c.8162C>A p.S2721Y | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.913); catalogued as COSV67207408; called by muse, varscan2
- LRP1B | c.5821C>T p.Q1941* | Nonsense Mutation (SNP) | VAF 14/240 reads (6%) | catalogued as COSV67207411; called by muse, mutect2
- LRRC37B | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 27/411 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1481802573, COSV58951918; called by muse, mutect2
- MAGEA3 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 195/341 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV64755983; called by muse, mutect2, varscan2
- MAGI2 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV62647375; called by mutect2, varscan2
- MAMDC2 | c.988C>G p.Q330E | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV65857657; called by muse, mutect2, varscan2
- MAP2 | c.3766C>G p.Q1256E | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV52287906; called by muse, mutect2, varscan2
- MAP2 | c.4832C>T p.S1611L | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52287918; called by muse, mutect2
- MAP3K9 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200962207, COSV67120945; called by muse, mutect2, varscan2
- MBD5 | c.3547G>C p.E1183Q | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV68696413, COSV68698109; called by muse, mutect2
- MCM10 | c.1192G>A p.E398K (on ENST00000484800 / NM_182751.3; = p.E397K on NM_018518.5) | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as rs1404688436, COSV66333908; called by muse, mutect2, varscan2
- MDM1 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57445434, COSV57448855; called by muse, mutect2, varscan2
- MECOM | c.10G>A p.E4K (on ENST00000468789 / NM_001105078.4; = p.E192K on NM_004991.4) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs771927221, COSV52963029; called by muse, mutect2, varscan2
- MEF2A | c.580C>T p.P194S (on ENST00000557942 / NM_001319206.2; = p.P196S on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/388 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV57530169; called by muse, mutect2, varscan2
- MGAT5 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV56095757; called by muse, mutect2
- MLLT10 | c.1878+1G>T p.X626_splice (on ENST00000307729 / NM_001195626.3; = p.X642_splice on NM_004641.3) | Splice Site (SNP) | VAF 33/86 reads (38%) | catalogued as COSV56994402, COSV57000475; called by muse, mutect2, varscan2
- MRGPRX1 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57106720; called by muse, mutect2, varscan2
- MS4A1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.165); catalogued as COSV61941831; called by muse, mutect2
- MSANTD2 | c.976G>A p.E326K (on ENST00000374979 / NM_001308027.2; = p.E274K on NM_024631.4) | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as COSV53448447; called by muse, mutect2
- MTDH | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV60343619; called by muse, mutect2, varscan2
- MTERF3 | c.635dup p.N212Kfs*7 | Frame Shift Ins (INS) | VAF 51/518 reads (10%) | catalogued as rs759886730; called by mutect2, pindel
- MUC16 | c.16868C>G p.P5623R | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV67448929, COSV67460035; called by muse, mutect2, varscan2
- MYBPC1 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV62252425; called by muse, mutect2
- MYCBP2 | c.12561C>T p.L4187= (on ENST00000357337; = p.L4225= on NM_015057.5) | Splice Region (SNP) | VAF 6/110 reads (5%) | catalogued as COSV62015630; called by muse, mutect2
- MYH8 | c.5119C>A p.Q1707K | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.665); catalogued as COSV67963388; called by muse, varscan2
- MYH9 | c.4250G>A p.R1417Q | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV53384968; called by muse, mutect2
- MYH9 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV53384978; called by muse, mutect2
- MYLIP | c.1163T>C p.M388T | Missense Mutation (SNP) | VAF 79/486 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV62766637; called by muse, mutect2, varscan2
- MYLK | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 84/731 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as COSV60608646; called by muse, mutect2, varscan2
- NAALADL1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752886257, COSV60523012; called by muse, mutect2, varscan2
- NAPEPLD | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV58521940; called by muse, mutect2, varscan2
- NAT2 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV54061817; called by muse, mutect2, varscan2
- NAV3 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as rs998849085, COSV57074504; called by muse, mutect2, varscan2
- NCAPG | c.2599C>T p.L867F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1243603313, COSV52269621; called by muse, mutect2
- NDFIP2 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54527639; called by muse, mutect2, varscan2
- NDRG3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as COSV62421659; called by muse, mutect2
- NECTIN1 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as rs371752868, COSV50599002, COSV50610354; called by muse, mutect2, varscan2
- NEFM | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as COSV55331632, COSV55335031; called by muse, mutect2, varscan2
- NEXN | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57356599; called by muse, mutect2, varscan2
- NFKBIE | c.1180G>A p.A394T (on ENST00000275015; = p.A255T on NM_004556.3) | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV51488776; called by muse, mutect2, varscan2
- NFU1 | c.473C>T p.S158L (on ENST00000410022 / NM_001002755.4; = p.S134L on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1314130766, COSV58006169; called by muse, mutect2, varscan2
- NID2 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV53494494; called by muse, mutect2
- NIPSNAP1 | c.458G>T p.R153M | Missense Mutation (SNP) | VAF 121/411 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV53342375; called by muse, mutect2, varscan2
- NKX2-2 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65819417; called by muse, mutect2, varscan2
- NLGN1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 58/627 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV64330145; called by muse, mutect2
- NOVA1 | c.1368G>T p.Q456H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57475358; called by muse, mutect2, varscan2
- NPFFR2 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV58148736; called by muse, mutect2, varscan2
- NR1H4 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV51851120; called by muse, mutect2, varscan2
- NRXN1 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV68011747; called by muse, mutect2
- NUP153 | c.3833G>C p.G1278A | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV50448315; called by muse, mutect2, varscan2
- NUP155 | c.3221G>C p.R1074T (on ENST00000231498 / NM_153485.3; = p.R1015T on NM_004298.4) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV51526158; called by muse, mutect2
- NVL | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV55871650; called by muse, mutect2, varscan2
- OR1E1 | c.904A>G p.S302G | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1472495261, COSV59458758; called by muse, mutect2, varscan2
- OR2C3 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100825788, COSV63574842; called by muse, mutect2, varscan2
- OR2L2 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 118/485 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as rs753145578, COSV63551776; called by muse, mutect2, varscan2
- OR2T3 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 40/818 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62082206, COSV62083764; called by muse, mutect2
- OR51I2 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58298469; called by muse, mutect2, varscan2
- OR5AC2 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 88/783 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62279315; called by muse, mutect2, varscan2
- OR8J3 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV56880195, COSV56880522; called by muse, mutect2, varscan2
- OR9G1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56449961; called by muse, mutect2, varscan2
- OTUD7B | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299787891, COSV64915115; called by muse, mutect2, varscan2
- PARP2 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51638671; called by muse, mutect2, varscan2
- PARP4 | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV67961420; called by muse, mutect2, varscan2
- PCDH11X | c.3553C>T p.H1185Y | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53458283; called by muse, mutect2, varscan2
- PCDH11Y | c.2177T>A p.V726E (on ENST00000400457 / NM_032973.2; = p.V715E on NM_032971.3) | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV99291906; called by muse, mutect2, varscan2
- PCDH15 | c.3631C>A p.H1211N | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.247); catalogued as COSV57293581; called by muse, mutect2, varscan2
- PCDH15 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 83/387 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57293610; called by muse, mutect2, varscan2
- PDILT | c.407A>T p.K136I | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56701184; called by muse, mutect2
- PDPR | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV55350931; called by muse, mutect2, varscan2
- PEAR1 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV52772444; called by muse, mutect2
- PEAR1 | c.2515C>G p.P839A | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV52772452; called by muse, mutect2, varscan2
- PGLYRP2 | c.1642-1G>A p.X548_splice | Splice Site (SNP) | VAF 35/296 reads (12%) | catalogued as COSV99484103; called by muse, mutect2, varscan2
- PHF21B | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV57557648; called by muse, mutect2, varscan2
- PIK3CB | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56685158; called by muse, mutect2
- PKHD1 | c.6532C>G p.L2178V | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV61870850; called by muse, mutect2, varscan2
- PLA2R1 | c.3674C>G p.S1225* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as COSV51777504; called by muse, mutect2, varscan2
- PLCE1 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53346439; called by muse, mutect2
- PLCH1 | c.1843G>A p.D615N (on ENST00000340059 / NM_001130960.2; = p.D627N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/324 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs997520185, COSV58193515; called by muse, mutect2, varscan2
- PLEKHG3 | c.979C>T p.R327W (on ENST00000394691; = p.R383W on NM_001308147.2) | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368245076; called by muse, mutect2
- PLOD2 | c.1866G>C p.W622C | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51463873, COSV51463971; called by muse, mutect2, varscan2
- PLS1 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 31/720 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61833525; called by muse, mutect2
- PLXNA4 | c.5308T>G p.C1770G | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58118472; called by muse, mutect2, varscan2
- POLQ | c.4883C>T p.S1628L | Missense Mutation (SNP) | VAF 53/816 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV51749788; called by muse, mutect2
- POLR2B | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58899869; called by muse, mutect2, varscan2
- PPP1R16A | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs762567550, COSV52952862; called by muse, mutect2, varscan2
- PPP1R9A | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56889480, COSV56908149; called by muse, mutect2, varscan2
- PSG8 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 44/447 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV60610967; called by muse, mutect2, varscan2
- PTPRD | c.1277C>A p.A426E | Missense Mutation (SNP) | VAF 156/317 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61938891; called by muse, mutect2, varscan2
- PTPRR | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs1244550355, COSV51729813; called by muse, mutect2, varscan2
- PYGO2 | c.138G>C p.R46S | Missense Mutation (SNP) | VAF 84/1826 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV63756855, COSV63757439; called by muse, mutect2
- PYHIN1 | c.1143G>C p.K381N | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV63722114; called by muse, mutect2, varscan2
- RAB38 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54712589, COSV54717115; called by muse, varscan2
- RALGAPB | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 40/564 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53436746, COSV53440725; called by muse, mutect2
- RARB | c.1027G>C p.E343Q (on ENST00000383772 / NM_001290216.2; = p.E336Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV51970894, COSV99979096; called by muse, mutect2
- RBAK | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs760043040, COSV62330827, COSV62331233; called by muse, mutect2, varscan2
- REST | c.1740G>C p.K580N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV58360191; called by muse, mutect2, varscan2
- RETREG3 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53816875; called by muse, mutect2, varscan2
- RGL1 | c.1187A>G p.N396S (on ENST00000360851 / NM_001297672.2; = p.N431S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV58983317; called by muse, mutect2, varscan2
- RGS3 | c.3492G>T p.Q1164H (on ENST00000350696 / NM_001282923.2; = p.Q883H on NM_130795.4) | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59515009; called by muse, mutect2, varscan2
- RIC8B | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV62693234, COSV62694107; called by muse, mutect2
- RIMS1 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1414432029, COSV53450436; called by muse, mutect2, varscan2
- RNF111 | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1566939511, COSV62085220; called by muse, mutect2
- RNF43 | c.2241G>A p.W747* | Nonsense Mutation (SNP) | VAF 93/439 reads (21%) | catalogued as COSV68457688; called by muse, mutect2, varscan2
- RPA4 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 15/165 reads (9%) | catalogued as COSV61266200; called by muse, mutect2
- RPAP1 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 6/132 reads (5%) | catalogued as COSV58538373; called by muse, mutect2
- RPGRIP1L | c.3105G>C p.E1035D | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV50905086; called by muse, mutect2
- RTL8A | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1244077884, COSV66188508; called by muse, mutect2, varscan2
- RXRG | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV63231759, COSV63231893; called by muse, mutect2, varscan2
- RYR2 | c.11929G>C p.D3977H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as CM0910994, COSV63679472; called by muse, mutect2, varscan2
- SAMD15 | c.1639C>G p.P547A | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV53626044; called by muse, mutect2, varscan2
- SCARB1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs767638385, COSV55546549; called by muse, mutect2, varscan2
- SCN3A | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51807418; called by muse, mutect2, varscan2
- SCYL2 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.058); catalogued as COSV62568424; called by muse, mutect2
- SDHB | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM061956, COSV64965149; called by muse, mutect2, varscan2
- SDK1 | c.1485G>A p.M495I | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV67364811; called by muse, mutect2, varscan2
- SECISBP2L | c.2926A>T p.I976F (on ENST00000559471 / NM_001193489.2; = p.I931F on NM_014701.4) | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.274); catalogued as COSV55933895; called by muse, mutect2
- SECISBP2L | c.2924C>T p.S975F (on ENST00000559471 / NM_001193489.2; = p.S930F on NM_014701.4) | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55933903; called by muse, mutect2
- SETBP1 | c.3062G>T p.R1021M | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56319229; called by muse, mutect2, varscan2
- SETD3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as COSV59283816, COSV59286066; called by muse, mutect2, varscan2
- SFMBT2 | c.1276T>C p.C426R | Missense Mutation (SNP) | VAF 142/458 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100739252; called by mutect2, varscan2
- SFXN3 | c.976T>C p.*326Rext*42 | Nonstop Mutation (SNP) | VAF 53/269 reads (20%) | catalogued as COSV56519725; called by muse, mutect2, varscan2
- SGCA | c.11C>A p.T4K | Missense Mutation (SNP) | VAF 107/769 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV56248990; called by muse, mutect2, varscan2
- SGCD | c.449C>G p.S150C (on ENST00000435422 / NM_001128209.2; = p.S151C on NM_000337.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV61907280; called by muse, mutect2, varscan2
- SH3GL1 | c.999C>G p.I333M | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53656785; called by muse, mutect2, varscan2
- SHANK2 | c.5105C>T p.S1702L | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.423); catalogued as rs1555149232, COSV53594516; called by muse, mutect2
- SHROOM3 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV56027460; called by muse, mutect2, varscan2
- SIN3B | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV56132534; called by muse, mutect2, varscan2
- SKIDA1 | c.2257C>G p.Q753E | Missense Mutation (SNP) | VAF 111/660 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1451276474, COSV71610396; called by muse, mutect2, varscan2
- SLC17A6 | c.1482T>A p.Y494* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV54135457; called by muse, mutect2, varscan2
- SLC22A8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60324627; called by muse, mutect2, varscan2
- SLC25A2 | c.877A>T p.M293L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53403532; called by muse, mutect2, varscan2
- SLC25A2 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV53403543; called by muse, mutect2, varscan2
- SLC37A1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1382025536, COSV61402095; called by muse, mutect2, varscan2
- SLC4A4 | c.1412C>T p.S471L (on ENST00000264485 / NM_001098484.3; = p.S427L on NM_003759.4) | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM043580, COSV52617533; called by muse, mutect2, varscan2
- SLC5A8 | c.677G>T p.R226I | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73310529; called by muse, mutect2, varscan2
- SLITRK2 | c.95G>C p.R32P | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV59424688; called by muse, mutect2, varscan2
- SLITRK2 | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV59424694; called by muse, mutect2, varscan2
- SLITRK5 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV61522200; called by muse, mutect2
- SMG8 | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV56284871; called by muse, mutect2, varscan2
- SMURF1 | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 39/653 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63156965; called by muse, mutect2
- SOGA3 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV64106235; called by muse, mutect2
- SORCS3 | c.1535T>A p.V512E | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63807714; called by muse, mutect2, varscan2
- SP140L | c.625A>G p.K209E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV54743019; called by muse, mutect2, varscan2
- SPACA1 | c.803G>C p.R268T | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as COSV52759560; called by muse, mutect2, varscan2
- SPAG11B | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.911); catalogued as COSV99873107; called by muse, mutect2, varscan2
- SPATA4 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV54589530; called by muse, mutect2, varscan2
- SPATA4 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); catalogued as COSV54589542; called by muse, mutect2, varscan2
- SPEG | c.6748C>T p.Q2250* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100404925; called by muse, mutect2, varscan2
- SPHKAP | c.3851G>T p.G1284V | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60875537; called by muse, mutect2, varscan2
- SPINK2 | c.56-1G>T p.X19_splice | Splice Site (SNP) | VAF 30/198 reads (15%) | catalogued as COSV50534171; called by muse, mutect2, varscan2
- SRCAP | c.848A>T p.D283V | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV52670840; called by muse, mutect2, varscan2
- SRSF2 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57971481, COSV57972944; called by muse, mutect2, varscan2
- STK36 | c.3589A>G p.M1197V | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1301571284, COSV55325780; called by muse, mutect2, varscan2
- STOX1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776848468, COSV53814300; called by muse, mutect2, varscan2
- STRIP1 | c.1831C>A p.P611T | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63930492; called by muse, mutect2, varscan2
- SUZ12 | c.1375A>G p.K459E | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV59499348; called by muse, mutect2, varscan2
- SYNE1 | c.19063C>G p.L6355V (on ENST00000367255 / NM_182961.4; = p.L6284V on NM_033071.3) | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV54958375; called by muse, mutect2, varscan2
- SYNE1 | c.3178G>C p.E1060Q (on ENST00000367255 / NM_182961.4; = p.E1067Q on NM_033071.3) | Missense Mutation (SNP) | VAF 13/356 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54958425; called by muse, mutect2
- TAAR1 | c.888C>G p.N296K | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51588430; called by muse, mutect2, varscan2
- TAS2R10 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV53700898, COSV53701248; called by muse, mutect2, varscan2
- TCEAL6 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1556365991, COSV65653896; called by muse, mutect2, varscan2
- TET1 | c.2742G>C p.E914D | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV65383956; called by muse, mutect2
- TEX55 | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55210044, COSV55210726; called by muse, mutect2
- TFAP2D | c.1010T>A p.M337K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs988203120, COSV50412622; called by muse, mutect2, varscan2
- TGFB2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.313); catalogued as rs749309877, COSV65108900; called by muse, mutect2, varscan2
- THAP1 | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 63/570 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54272979; called by muse, mutect2, varscan2
- TICRR | c.1725G>T p.M575I | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254350348, COSV51540568; called by muse, mutect2, varscan2
- TMC4 | c.1591G>A p.E531K (on ENST00000617472 / NM_001145303.3; = p.E525K on NM_144686.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs746666219, COSV55826910; called by muse, mutect2
- TMCO3 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as rs566169866, COSV64806926; called by muse, mutect2, varscan2
- TNKS | c.3474G>C p.L1158F | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60055708; called by muse, mutect2
- TNXB | c.10234G>A p.E3412K (on ENST00000647633; = p.E3165K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.774); catalogued as rs765598398, COSV64477482; called by muse, mutect2, varscan2
- TOP1 | c.183C>G p.H61Q | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.599); catalogued as COSV63693556; called by muse, mutect2
- TPD52L3 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 24/246 reads (10%) | catalogued as COSV58828229; called by muse, mutect2
- TPO | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as CS002686, COSV61093388; called by muse, mutect2, varscan2
- TRIL | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV59866901; called by muse, mutect2, varscan2
- TRIM69 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 17/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57803479; called by muse, mutect2
- TRIM75P | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV72295825; called by muse, mutect2, varscan2
- TRIOBP | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV60376191; called by muse, mutect2, varscan2
- TSGA10IP | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73245265; called by muse, mutect2, varscan2
- TTC21B | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV54629576; called by muse, mutect2, varscan2
- TTLL4 | c.2864C>G p.S955C | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV51435957; called by muse, mutect2
- TTN | c.57700G>A p.D19234N (on ENST00000591111; = p.D11810N on NM_003319.4) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | PolyPhen benign (0.006); catalogued as COSV59903051; called by muse, mutect2, varscan2
- TTN | c.53231C>G p.P17744R (on ENST00000591111; = p.P10320R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV59994231; called by muse, mutect2, varscan2
- TTN | c.32578G>T p.E10860* (on ENST00000591111; = p.E9933* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/130 reads (18%) | catalogued as COSV59994255; called by muse, mutect2, varscan2
- TTN | c.14608C>A p.L4870M (on ENST00000591111; = p.L3943M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/209 reads (22%) | PolyPhen benign (0.341); catalogued as COSV100620335, COSV59994265; called by muse, mutect2, varscan2
- TYR | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV54473673; called by muse, mutect2, varscan2
- TYR | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.181); catalogued as rs758612817, COSV54473446, COSV99635571; called by muse, mutect2, varscan2
- UGGT2 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65074013; called by muse, mutect2
- UHRF1BP1L | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1481334953, COSV54436333; called by muse, mutect2
- UNC13A | c.4205G>A p.G1402E | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV53189024; called by muse, mutect2, varscan2
- UNC13C | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.097); catalogued as rs1322185595, COSV52863536; called by muse, mutect2
- UTP20 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV55375458; called by muse, mutect2, varscan2
- UTRN | c.3826C>G p.L1276V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62332990; called by muse, mutect2
- VAT1L | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56817993; called by muse, mutect2
- VEPH1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 22/684 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62878097; called by muse, mutect2
- VIPR2 | c.239G>A p.S80N | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.636); catalogued as COSV51105319; called by muse, varscan2
- VPS13A | c.6089C>T p.S2030F | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV62428218; called by muse, mutect2
- VPS13B | c.7011G>A p.M2337I | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV62138992; called by muse, mutect2
- VPS13C | c.9704C>T p.S3235L (on ENST00000644861 / NM_020821.3; = p.S3192L on NM_017684.5) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51152166; called by muse, mutect2
- WDR4 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 100/842 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as COSV57733129; called by muse, mutect2, varscan2
- WNK1 | c.2677C>G p.P893A | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1206597194, COSV60030904; called by muse, mutect2
- XIRP2 | c.1732G>A p.E578K (on ENST00000628543; = p.E753K on NM_152381.6) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54689362; called by muse, mutect2
- XRN1 | c.2419C>G p.Q807E | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53810482; called by muse, mutect2
- ZBBX | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as COSV56781599, COSV56787291; called by muse, mutect2, varscan2
- ZBTB24 | c.1823C>G p.S608* | Nonsense Mutation (SNP) | VAF 12/217 reads (6%) | catalogued as COSV57781769; called by muse, mutect2
- ZBTB24 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 44/960 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV57781780; called by muse, mutect2
- ZC3H6 | c.2366G>C p.R789T | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV59667175; called by muse, mutect2, varscan2
- ZFHX4 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV50682953; called by muse, mutect2, varscan2
- ZFHX4 | c.4039G>T p.E1347* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV50683097; called by muse, mutect2, varscan2
- ZNF107 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV61328125; called by muse, mutect2
- ZNF227 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.113); catalogued as COSV57312013; called by muse, mutect2, varscan2
- ZNF236 | c.675C>G p.F225L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV53486287; called by muse, mutect2, varscan2
- ZNF239 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV60018467; called by muse, mutect2, varscan2
- ZNF267 | c.1850C>G p.S617* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as COSV56252196; called by muse, mutect2
- ZNF429 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV61915684; called by muse, mutect2
- ZNF43 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV61683593; called by muse, mutect2, varscan2
- ZNF438 | c.2479G>C p.E827Q | Missense Mutation (SNP) | VAF 123/821 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV59191788, COSV59194159; called by muse, mutect2, varscan2
- ZNF467 | c.1635C>G p.C545W | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766245282, COSV57372668; called by muse, mutect2, varscan2
- ZNF493 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV62749807; called by muse, mutect2
- ZNF519 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73913295; called by muse, mutect2
- ZNF536 | c.2569C>T p.Q857* | Nonsense Mutation (SNP) | VAF 26/340 reads (8%) | catalogued as COSV62822516; called by muse, mutect2
- ZNF559 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as COSV57835449; called by muse, mutect2, varscan2
- ZNF583 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | catalogued as COSV52402037; called by muse, mutect2
- ZNF594 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as COSV68385102; called by muse, mutect2
- ZNF665 | c.524G>A p.G175E (on ENST00000600412; = p.G240E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67214562; called by muse, mutect2, varscan2
- ZNF692 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1441669129, COSV60659125; called by muse, mutect2, varscan2
- ZNF804A | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100169775, COSV56444713; called by muse, mutect2, varscan2
- ZNF816 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV54410947; called by muse, mutect2, varscan2
- ZNF827 | c.2953G>C p.D985H | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV65226325; called by muse, mutect2
- ZNF98 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63335931; called by muse, mutect2, varscan2
- ZNFX1 | c.2591T>G p.L864R | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65574759; called by muse, mutect2
- AGAP4 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- ARID1A | c.3714del p.A1239Lfs*30 | Frame Shift Del (DEL) | VAF 33/179 reads (18%) | called by mutect2, pindel, varscan2
- CA2 | c.445del p.X149_splice | Splice Site (DEL) | VAF 26/134 reads (19%) | called by mutect2, pindel, varscan2
- DNM1L | c.1760_1761del p.G587Efs*12 (on ENST00000549701 / NM_012062.5; = p.G550Efs*12 on NM_005690.4) | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- MYO16 | c.4872del p.V1625Wfs*16 | Frame Shift Del (DEL) | VAF 33/67 reads (49%) | called by mutect2, pindel, varscan2
- NOS1 | c.1389del p.I464Sfs*101 | Frame Shift Del (DEL) | VAF 40/158 reads (25%) | called by mutect2, pindel, varscan2
- RASA1 | c.435_447del p.L146Sfs*24 | Frame Shift Del (DEL) | VAF 58/117 reads (50%) | called by mutect2, pindel*
- STK33 | c.786+1del p.X262_splice | Splice Site (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- SYNE4 | c.518G>C p.W173S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2
- TENM4 | c.6436G>C p.D2146H | Missense Mutation (SNP) | VAF 5/123 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TP53 | c.872_881del p.K291Sfs*51 | Frame Shift Del (DEL) | VAF 64/194 reads (33%) | called by mutect2, pindel, varscan2
- TRAV24 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS15 | c.2610C>T p.A870= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs768164805, COSV100143509; called by mutect2, varscan2
- ADPRH | c.78C>T p.F26= | Silent (SNP) | VAF 14/227 reads (6%) | catalogued as rs1428722850, COSV63694800; called by muse, mutect2
- ALG2 | c.792G>C p.L264= | Silent (SNP) | VAF 38/392 reads (10%) | catalogued as COSV53059289; called by muse, mutect2
- ALMS1 | c.1689G>A p.Q563= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as COSV52507908; called by muse, mutect2, varscan2
- ANK3 | c.4863C>T p.S1621= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV55053559; called by muse, mutect2, varscan2
- ANKRD30A | c.2019A>C p.S673= (on ENST00000611781; = p.S617= on NM_052997.2) | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV64608472; called by muse, mutect2, varscan2
- AP3S2 | c.513A>G p.P171= | Silent (SNP) | VAF 159/516 reads (31%) | catalogued as COSV100318688, COSV60518037; called by muse, mutect2, varscan2
- APOOL | c.144G>T p.P48= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs755580484, COSV64271011, COSV64271529; called by muse, mutect2, varscan2
- ARHGAP31 | c.1488C>T p.L496= | Silent (SNP) | VAF 48/533 reads (9%) | catalogued as COSV51791759; called by muse, mutect2
- ARHGEF9 | c.984C>T p.I328= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1291302762, COSV53637190; called by muse, mutect2, varscan2
- ARNTL2 | c.618C>T p.F206= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as rs758363984, COSV53824193; called by muse, varscan2
- ASB13 | c.750G>A p.L250= | Silent (SNP) | VAF 62/350 reads (18%) | catalogued as COSV63090466; called by muse, mutect2, varscan2
- ASB3 | c.1420C>T p.L474= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV55074446, COSV55075158; called by muse, mutect2, varscan2
- BCHE | c.1299C>T p.F433= | Silent (SNP) | VAF 36/333 reads (11%) | catalogued as COSV52255757; called by muse, mutect2, varscan2
- BLK | c.1011G>C p.L337= | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as COSV52051108; called by muse, mutect2, varscan2
- BNC2 | c.1929G>A p.E643= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs765607483, COSV66145094; called by muse, mutect2, varscan2
- BRPF3 | c.3240G>C p.V1080= | Silent (SNP) | VAF 29/202 reads (14%) | catalogued as COSV60206900; called by muse, mutect2, varscan2
- CACNA1G | c.2853C>A p.G951= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV61724741; called by muse, mutect2, varscan2
- CADM4 | c.1011C>T p.I337= | Silent (SNP) | VAF 46/262 reads (18%) | catalogued as COSV55928561; called by mutect2, varscan2
- CAPN2 | c.1842C>A p.I614= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs779179250, COSV54335617, COSV54337215; called by muse, mutect2, varscan2
- CASS4 | c.669G>A p.V223= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as rs1284687254, COSV64386038; called by muse, mutect2, varscan2
- CCDC116 | c.1359C>T p.F453= | Silent (SNP) | VAF 30/278 reads (11%) | catalogued as rs781429637, COSV53039210; called by muse, mutect2, varscan2
- CCDC65 | c.168G>A p.L56= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV57195356; called by muse, mutect2
- CDK11A | c.1614G>A p.V538= (on ENST00000378633 / NM_001313896.2; = p.V535= on NM_024011.4) | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV52307175; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1110C>A p.I370= (on ENST00000357886 / NM_001365728.1; = p.I356= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1394377690, COSV59426622; called by muse, mutect2, varscan2
- CDT1 | c.240C>T p.P80= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as rs774848863, COSV56347932; called by muse, mutect2, varscan2
- CLK2 | c.69G>C p.R23= | Silent (SNP) | VAF 14/450 reads (3%) | catalogued as COSV100751886, COSV62876977; called by muse, mutect2
- CMPK2 | c.741C>T p.I247= | Silent (SNP) | VAF 30/374 reads (8%) | catalogued as COSV56774450; called by muse, mutect2
- COL6A5 | c.6624C>T p.F2208= (on ENST00000312481; = p.F2204= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs765080229; called by muse, varscan2
- CPNE7 | c.1204C>T p.L402= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs1052271089, COSV52012226; called by muse, mutect2, varscan2
- DAGLB | c.1080G>T p.V360= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV51703362; called by muse, mutect2, varscan2
- DERL1 | c.117C>T p.L39= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1339215449, COSV52364634; called by muse, mutect2, varscan2
- DHX37 | c.174G>A p.K58= | Silent (SNP) | VAF 18/416 reads (4%) | catalogued as COSV58133709; called by muse, mutect2
- DIDO1 | c.4413C>T p.S1471= | Silent (SNP) | VAF 18/460 reads (4%) | catalogued as rs1417075666, COSV56619517; called by muse, mutect2
- DMXL2 | c.1731G>T p.T577= | Silent (SNP) | VAF 48/197 reads (24%) | catalogued as COSV51844540; called by muse, mutect2, varscan2
- DRD5 | c.1167C>T p.I389= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV58577607; called by muse, mutect2, varscan2
- DST | c.11898G>A p.Q3966= (on ENST00000361203 / NM_001374722.1; = p.Q1554= on NM_015548.5) | Silent (SNP) | VAF 20/313 reads (6%) | catalogued as rs1038893936, COSV55009052; called by muse, mutect2
- EMILIN2 | c.2713C>T p.L905= | Silent (SNP) | VAF 21/252 reads (8%) | catalogued as COSV54422794; called by muse, mutect2
- ETV2 | c.960C>T p.F320= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1399865329, COSV55837626; called by muse, mutect2
- FBXO21 | c.1380A>T p.L460= (on ENST00000330622 / NM_033624.3; = p.L453= on NM_015002.3) | Silent (SNP) | VAF 312/1010 reads (31%) | catalogued as COSV57972359; called by muse, mutect2, varscan2
- FGF12 | c.120G>T p.L40= | Silent (SNP) | VAF 166/542 reads (31%) | catalogued as COSV53151596, COSV53160969, COSV99280973; called by muse, mutect2, varscan2
- FOSL1 | c.246C>T p.V82= | Silent (SNP) | VAF 32/226 reads (14%) | catalogued as COSV57027381; called by muse, mutect2, varscan2
- FXR1 | c.864T>A p.V288= | Silent (SNP) | VAF 42/426 reads (10%) | catalogued as rs1357477820, COSV59762399; called by muse, mutect2
- FZD6 | c.195A>T p.A65= | Silent (SNP) | VAF 53/232 reads (23%) | catalogued as COSV62471150; called by muse, mutect2, varscan2
- GALNS | c.231T>C p.P77= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV51936710; called by muse, mutect2, varscan2
- GAP43 | c.366G>A p.Q122= | Silent (SNP) | VAF 50/106 reads (47%) | catalogued as COSV59343592; called by muse, mutect2, varscan2
- GFAP | c.1221C>G p.L407= | Silent (SNP) | VAF 19/654 reads (3%) | catalogued as COSV53654502; called by muse, mutect2
- GGNBP2 | c.240G>C p.L80= | Silent (SNP) | VAF 77/445 reads (17%) | called by muse, mutect2, varscan2
- GPAA1 | c.1291C>T p.L431= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV60155590; called by muse, mutect2, varscan2
- GPR83 | c.759C>A p.L253= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV54718288; called by muse, mutect2, varscan2
- GRPR | c.1122C>T p.I374= | Silent (SNP) | VAF 81/192 reads (42%) | catalogued as COSV66668905; called by muse, mutect2, varscan2
- GYS1 | c.567C>T p.C189= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as COSV54402323; called by muse, mutect2, varscan2
- HERC2 | c.6066G>C p.R2022= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV55318951; called by muse, mutect2
- HEYL | c.690G>T p.L230= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV65721521; called by muse, varscan2
- HS3ST1 | c.663C>T p.I221= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1271724104, COSV50023369; called by muse, mutect2, varscan2
- HTR5A | c.24C>A p.T8= | Silent (SNP) | VAF 51/305 reads (17%) | catalogued as COSV55282350; called by muse, mutect2, varscan2
- IFNA17 | c.348G>A p.L116= | Silent (SNP) | VAF 33/358 reads (9%) | catalogued as COSV69738136; called by muse, mutect2
- IGHV1OR21-1 | c.261C>T p.V87= | Silent (SNP) | VAF 30/920 reads (3%) | called by muse, mutect2
- IQCA1 | c.288G>T p.T96= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV54500139, COSV54504849; called by muse, mutect2, varscan2
- ISLR | c.363C>T p.L121= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV51433497; called by muse, mutect2, varscan2
- KAT2B | c.2205C>T p.I735= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV55428467; called by muse, mutect2, varscan2
- KCNH4 | c.1971G>A p.L657= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as COSV52916721; called by muse, varscan2
- KCNH7 | c.681C>A p.P227= | Silent (SNP) | VAF 46/258 reads (18%) | catalogued as COSV59793902; called by muse, mutect2, varscan2
- KHDRBS3 | c.846G>A p.Q282= | Silent (SNP) | VAF 53/518 reads (10%) | catalogued as COSV63417064, COSV63421286; called by muse, mutect2
- KRTAP13-2 | c.390G>T p.L130= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs145274953; called by muse, mutect2, varscan2
- LARS1 | c.972C>T p.F324= (on ENST00000394434 / NM_020117.11; = p.F297= on NM_016460.3) | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs1433685852, COSV50974376; called by muse, mutect2, varscan2
- LILRA2 | c.117C>T p.I39= | Silent (SNP) | VAF 46/438 reads (11%) | catalogued as COSV52190553; called by muse, varscan2
- LPL | c.168C>G p.L56= | Silent (SNP) | VAF 45/401 reads (11%) | catalogued as COSV60930892; called by muse, mutect2, varscan2
- LRFN5 | c.240G>T p.L80= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV53252121; called by muse, mutect2, varscan2
- LRP1 | c.8103C>T p.F2701= | Silent (SNP) | VAF 33/247 reads (13%) | catalogued as rs368477109; called by muse, mutect2, varscan2
- LRP2 | c.12024C>T p.I4008= | Silent (SNP) | VAF 12/215 reads (6%) | catalogued as COSV55549596; called by muse, mutect2
- LRP2 | c.3855C>T p.H1285= | Silent (SNP) | VAF 84/278 reads (30%) | catalogued as COSV55549612; called by muse, mutect2, varscan2
- LRRK2 | c.6966G>A p.K2322= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV100111005, COSV54150145; called by muse, mutect2, varscan2
- MAGEC3 | c.1806C>T p.S602= | Silent (SNP) | VAF 45/184 reads (24%) | catalogued as COSV53578895, COSV68924219; called by muse, mutect2, varscan2
- MARCO | c.36C>G p.L12= | Silent (SNP) | VAF 27/220 reads (12%) | catalogued as COSV59053690; called by muse, mutect2, varscan2
- MAST4 | c.2031G>T p.T677= (on ENST00000403625 / NM_001164664.2; = p.T488= on NM_015183.3) | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as rs780433285, COSV55122174; called by muse, mutect2, varscan2
- MCM2 | c.1755C>T p.L585= | Silent (SNP) | VAF 73/593 reads (12%) | catalogued as rs780368141, COSV54033223; called by muse, mutect2, varscan2
- MEMO1 | c.273C>T p.S91= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV54451378; called by muse, mutect2
- MNX1 | c.834C>G p.L278= | Silent (SNP) | VAF 3/56 reads (5%) | catalogued as COSV53318004; called by muse, mutect2
- MPP5 | c.1437G>A p.K479= | Silent (SNP) | VAF 33/179 reads (18%) | catalogued as COSV55529214; called by muse, mutect2, varscan2
- NBAS | c.609C>T p.V203= | Silent (SNP) | VAF 50/319 reads (16%) | catalogued as rs753177562, COSV55718603; called by muse, mutect2, varscan2
- NOD1 | c.1623C>T p.L541= | Silent (SNP) | VAF 21/392 reads (5%) | catalogued as COSV56112032; called by muse, mutect2
- NOD1 | c.945C>T p.A315= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV56112039; called by muse, mutect2
- NPAS4 | c.966C>T p.L322= | Silent (SNP) | VAF 20/350 reads (6%) | catalogued as COSV60649953; called by muse, mutect2
- NRIP1 | c.2466G>A p.L822= | Silent (SNP) | VAF 60/190 reads (32%) | catalogued as COSV59656764; called by muse, mutect2, varscan2
- OCA2 | c.363C>T p.I121= | Silent (SNP) | VAF 62/588 reads (11%) | catalogued as COSV62343475; called by muse, mutect2, varscan2
- OLFM2 | c.1014C>T p.T338= | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as COSV53429694; called by muse, mutect2, varscan2
- OR10G7 | c.123C>T p.L41= | Silent (SNP) | VAF 33/274 reads (12%) | catalogued as COSV57866717; called by muse, mutect2
- OR2A2 | c.132C>A p.I44= | Silent (SNP) | VAF 83/398 reads (21%) | catalogued as rs1239253476, COSV68871410, COSV68872565; called by muse, mutect2, varscan2
- OR2L3 | c.456G>T p.S152= | Silent (SNP) | VAF 184/508 reads (36%) | catalogued as rs781220819, COSV100741938, COSV63455019; called by muse, varscan2
- OR2T2 | c.906G>A p.L302= | Silent (SNP) | VAF 30/278 reads (11%) | catalogued as COSV100737714; called by muse, varscan2
- OR2T35 | c.903G>A p.L301= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as rs1388513369, COSV100442323; called by muse, mutect2, varscan2
- OR4A5 | c.156C>T p.S52= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs1240612187, COSV60522222; called by muse, mutect2, varscan2
- OR51A4 | c.768C>A p.I256= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as COSV66749320; called by muse, mutect2, varscan2
- OR52W1 | c.810T>C p.G270= | Silent (SNP) | VAF 285/1443 reads (20%) | catalogued as COSV60950817; called by muse, mutect2, varscan2
- OR5I1 | c.603C>A p.L201= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV56886427; called by muse, mutect2
- OR8J1 | c.633G>A p.L211= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV57317757, COSV57318202; called by muse, mutect2
- ORC4 | c.618G>A p.V206= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV51573132; called by muse, mutect2
- OSBP2 | c.2664G>A p.L888= | Silent (SNP) | VAF 38/347 reads (11%) | catalogued as COSV60241716; called by muse, mutect2, varscan2
- OTOA | c.228G>C p.L76= | Silent (SNP) | VAF 12/189 reads (6%) | catalogued as COSV53752469; called by muse, mutect2
- OTOGL | c.1290C>T p.L430= (on ENST00000547103; = p.L421= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as rs375008300; called by muse, mutect2, varscan2
- OXGR1 | c.855C>T p.I285= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as rs1240445214, COSV53657345; called by muse, mutect2, varscan2
- P2RY8 | c.603G>T p.L201= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV67177119; called by muse, mutect2, varscan2
- PARP10 | c.1005G>A p.L335= | Silent (SNP) | VAF 44/379 reads (12%) | catalogued as rs368685569; called by muse, mutect2, varscan2
- PCDHA2 | c.666C>T p.L222= | Silent (SNP) | VAF 67/418 reads (16%) | catalogued as COSV65366284; called by muse, mutect2, varscan2
- PCDHA5 | c.2244G>A p.S748= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as COSV65351336, COSV65357640; called by muse, varscan2
- PCNX3 | c.4122C>T p.F1374= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs200591552, COSV63136156; called by muse, mutect2, varscan2
- PDZD4 | c.1822C>A p.R608= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV51246218; called by muse, mutect2
- PLOD1 | c.780C>T p.F260= | Silent (SNP) | VAF 87/412 reads (21%) | catalogued as rs1022483147, COSV52143237; called by muse, mutect2, varscan2
- PLXNB2 | c.4272C>T p.L1424= | Silent (SNP) | VAF 50/758 reads (7%) | catalogued as rs751630630, COSV63781089, COSV63783418; called by muse, mutect2
- PPP2R3B | c.477G>A p.R159= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as COSV66813097; called by muse, mutect2, varscan2
- PRKX | c.405C>T p.F135= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs1443747010, COSV53323425; called by muse, mutect2, varscan2
- PRL | c.642C>G p.L214= | Silent (SNP) | VAF 50/552 reads (9%) | catalogued as COSV60591719, COSV60593220; called by muse, mutect2
- PRRC2B | c.3237G>T p.R1079= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV61936063; called by muse, mutect2, varscan2
- PRSS1 | c.411G>A p.T137= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as rs369013081, COSV61190980; called by muse, mutect2, varscan2
- PTN | c.66C>T p.F22= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV61964746; called by muse, mutect2, varscan2
- PXDN | c.2118C>T p.N706= | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as rs752768393, COSV53227154; called by muse, mutect2, varscan2
- RPH3A | c.1023A>G p.A341= (on ENST00000389385 / NM_001143854.2; = p.A337= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV66990727; called by muse, mutect2, varscan2
- RYR2 | c.4500C>G p.R1500= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV63679465; called by muse, mutect2, varscan2
- SAMD3 | c.730A>C p.R244= | Silent (SNP) | VAF 13/134 reads (10%) | catalogued as COSV63715234; called by muse, mutect2
- SERPINE2 | c.135G>A p.S45= | Silent (SNP) | VAF 44/329 reads (13%) | catalogued as rs771123562, COSV51456892; called by muse, mutect2, varscan2
- SGIP1 | c.1722C>T p.F574= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV52766519, COSV99390346; called by muse, mutect2, varscan2
- SIGLEC6 | c.699T>C p.N233= | Silent (SNP) | VAF 88/352 reads (25%) | catalogued as COSV58433364; called by muse, mutect2, varscan2
- SKI | c.498C>A p.I166= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV101049502, COSV66013340; called by muse, mutect2, varscan2
- SLC13A4 | c.1036C>T p.L346= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as COSV62460733; called by muse, mutect2, varscan2
- SLC26A9 | c.1116C>T p.L372= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs748003639, COSV61602116; called by muse, mutect2, varscan2
- SLC39A10 | c.1584G>A p.Q528= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV62766967; called by muse, mutect2
- SLCO2A1 | c.1278C>A p.A426= | Silent (SNP) | VAF 83/215 reads (39%) | catalogued as COSV60485032; called by muse, mutect2, varscan2
- SRGAP1 | c.546G>A p.L182= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV61896725; called by muse, mutect2
- SRSF2 | c.177C>T p.F59= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV57971488; called by muse, mutect2, varscan2
- SYT9 | c.522C>T p.L174= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs762941038, COSV59616707; called by muse, mutect2, varscan2
- TBX5 | c.117G>A p.P39= | Silent (SNP) | VAF 38/230 reads (17%) | catalogued as rs149030937; called by muse, mutect2, varscan2
- TEPP | c.72C>T p.F24= | Silent (SNP) | VAF 29/272 reads (11%) | catalogued as rs1206133107, COSV52043021; called by muse, mutect2, varscan2
- TGFB1I1 | c.1128C>T p.F376= (on ENST00000394863 / NM_001042454.3; = p.F359= on NM_015927.4) | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV62357733; called by muse, mutect2, varscan2
- TRPM6 | c.435C>A p.G145= | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as rs796075660, COSV62507587; called by muse, mutect2, varscan2
- TSPAN32 | c.642C>G p.L214= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs200678268, COSV51719509; called by muse, mutect2
- TTLL7 | c.2064C>T p.L688= | Silent (SNP) | VAF 13/193 reads (7%) | catalogued as COSV53081923, COSV53083527; called by muse, mutect2
- TUBGCP5 | c.384G>A p.E128= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, varscan2
- TXNRD1 | c.1539C>G p.V513= (on ENST00000525566 / NM_001093771.3; = p.V415= on NM_003330.4) | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV61598704; called by muse, mutect2, varscan2
- UBQLNL | c.1380G>A p.L460= | Silent (SNP) | VAF 40/296 reads (14%) | catalogued as COSV66493107; called by muse, mutect2, varscan2
- UBQLNL | c.663C>T p.I221= | Silent (SNP) | VAF 17/435 reads (4%) | catalogued as COSV66493117; called by muse, mutect2
- UTP15 | c.588G>A p.T196= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as rs780862161, COSV57140774; called by muse, mutect2, varscan2
- VAMP5 | c.168G>A p.Q56= | Silent (SNP) | VAF 47/383 reads (12%) | catalogued as COSV60498478; called by muse, mutect2, varscan2
- VPS13B | c.1104G>T p.G368= | Silent (SNP) | VAF 28/243 reads (12%) | catalogued as COSV62018328; called by muse, mutect2, varscan2
- XCL2 | c.330G>A p.V110= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV100892258; called by muse, mutect2, varscan2
- XRN2 | c.1152C>T p.V384= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as COSV65869187; called by muse, mutect2
- YTHDC1 | c.1590G>A p.R530= (on ENST00000344157 / NM_001031732.4; = p.R512= on NM_133370.4) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV60009793; called by muse, mutect2, varscan2
- ZC3H6 | c.3471G>A p.G1157= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs539203940, COSV59667189; called by muse, mutect2, varscan2
- ZFYVE28 | c.1062C>T p.D354= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs748342488, COSV52109026; called by muse, mutect2, varscan2
- ZNF165 | c.702G>A p.K234= | Silent (SNP) | VAF 61/336 reads (18%) | catalogued as rs1301184700, COSV66102307; called by muse, mutect2, varscan2
- ZNF169 | c.1647C>T p.R549= | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as rs769318101, COSV61763951; called by muse, mutect2, varscan2
- ZNF208 | c.2136G>A p.K712= | Silent (SNP) | VAF 29/216 reads (13%) | catalogued as rs1430208815, COSV68103826; called by muse, varscan2
- ZNF385B | c.1200C>T p.Y400= | Silent (SNP) | VAF 18/675 reads (3%) | catalogued as COSV61177069; called by muse, mutect2
- ZNF423 | c.3234C>G p.L1078= (on ENST00000563137 / NM_001379286.1; = p.L1070= on NM_015069.4) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV52185074; called by muse, mutect2, varscan2
- ZNF484 | c.714C>G p.L238= | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as COSV60257399; called by muse, mutect2
- ZNF638 | c.4422G>A p.L1474= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV52485404; called by muse, mutect2
- ZNF676 | c.1383C>A p.A461= (on ENST00000650058; = p.A429= on NM_001001411.3) | Silent (SNP) | VAF 62/288 reads (22%) | catalogued as COSV68092815; called by muse, varscan2
- ZNF689 | c.324C>T p.S108= | Silent (SNP) | VAF 17/356 reads (5%) | catalogued as rs1221286273, COSV54908190; called by muse, mutect2
- ZW10 | c.795G>A p.V265= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1408397043, COSV52315991; called by muse, mutect2
- C2orf66 | c.-15C>T | 5'UTR (SNP) | VAF 46/303 reads (15%) | catalogued as COSV61098783; called by muse, mutect2, varscan2
- DIRC1 | n.361G>T | RNA (SNP) | VAF 20/265 reads (8%) | catalogued as rs1358821861, COSV57366695; called by muse, mutect2
- ENSA | c.183+67G>C | Intron (SNP) | VAF 18/686 reads (3%) | called by muse, mutect2
- FAM74A3 | n.367T>A | RNA (SNP) | VAF 24/246 reads (10%) | catalogued as rs1032882162; called by muse, mutect2
- GLT8D1 | c.-1G>C | 5'UTR (SNP) | VAF 16/128 reads (13%) | catalogued as COSV56477055, COSV99803925; called by muse, mutect2, varscan2
- IZUMO4 | c.370+187C>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100642786; called by muse, mutect2
- KDM8 | c.-1G>A | 5'UTR (SNP) | VAF 72/521 reads (14%) | catalogued as rs542617450, COSV53732621; called by muse, varscan2
- KPNA4 | c.1032+392G>C | Intron (SNP) | VAF 44/446 reads (10%) | catalogued as COSV100515221; called by muse, mutect2, varscan2
- REG4 | c.*427C>G | 3'UTR (SNP) | VAF 10/270 reads (4%) | catalogued as COSV99858588; called by muse, mutect2
- RPP38 | chr10:15096467 G>C | 5'Flank (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- SNORD115-14 | n.9G>A | RNA (SNP) | VAF 82/1024 reads (8%) | catalogued as rs941709085; called by muse, mutect2
- ST8SIA2 | chr15:92472350 C>A | 3'Flank (SNP) | VAF 83/313 reads (27%) | called by muse, mutect2, varscan2
